Somatic mutation profile of tumor specimen C3N-02714-02 (aliquot CPT0177200006) from CPTAC case C3N-02714, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 23.4 years (8,551 days).
Specimen C3N-02714-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ec3a501-8d76-4eb4-aba9-2dc861ae55b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02714-71 (Blood Derived Normal), aliquot CPT0177310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdc6267e-46bd-4d02-808c-441c522ddf23

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 5, Intron 3, 5'UTR 2, RNA 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TIMM50 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 25/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244226820, COSV100067902; ClinVar: pathogenic; called by muse, mutect2
- BEST4 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 41/193 reads (21%) | catalogued as rs776266325; called by muse, mutect2, varscan2
- CDH19 | c.2157G>T p.Q719H | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV50964484; called by muse, mutect2
- CSMD3 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.467); catalogued as rs373340560, COSV52157437; called by muse, mutect2, varscan2
- FAM151B | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56474602; called by muse, mutect2
- GANAB | c.1509G>C p.W503C | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60468406; called by muse, mutect2
- ITIH5 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 35/538 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs749743981, COSV53669740; called by muse, mutect2
- MUC5B | c.4475C>T p.T1492M | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs567562795, COSV71591729; called by muse, mutect2
- NKD1 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 27/315 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749813334; called by muse, mutect2
- NPAS1 | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); catalogued as rs1400167838; called by muse, mutect2
- OR51B2 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.573); catalogued as rs751983525; called by muse, mutect2, varscan2
- OR5W2 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV100747611; called by muse, mutect2
- PCDHA13 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 68/788 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.225); catalogued as rs372048294; called by muse, mutect2
- RYR3 | c.4798G>A p.G1600S | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759747259, COSV66786064; called by muse, mutect2, varscan2
- SLFN12L | c.757G>C p.E253Q (on ENST00000260908 / NM_001363830.1; = p.E271Q on NM_001195790.1) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1206098779; called by muse, mutect2, varscan2
- TRIM55 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV52548946, COSV52550488; called by muse, mutect2, varscan2
- UGT1A8 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 20/276 reads (7%) | catalogued as rs771007460, COSV65077439; called by muse, mutect2
- WNT3 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.636); catalogued as rs139902701, COSV56646089; called by muse, mutect2
- ABCA13 | c.7883C>T p.S2628F | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2
- AJM1 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRWD3 | c.2565T>G p.S855R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COMP | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 38/447 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- DENND4B | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2
- HS6ST1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- LY75 | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- NAP1L5 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); called by muse, mutect2
- PKD1 | c.5693T>G p.V1898G | Missense Mutation (SNP) | VAF 16/550 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PLAAT3 | c.412A>T p.S138C | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2
- PLXND1 | c.1734G>T p.Q578H | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- POGLUT1 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM5 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- SLIT1 | c.3016A>G p.T1006A | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- SYF2 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TMX1 | c.388A>T p.K130* | Nonsense Mutation (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- TONSL | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2
- TP53 | c.930_937dup p.S313Tfs*35 | Frame Shift Ins (INS) | VAF 34/250 reads (14%) | called by mutect2, varscan2
- TSC2 | c.4147A>T p.S1383C | Missense Mutation (SNP) | VAF 48/599 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TTN | c.46193C>A p.S15398* (on ENST00000591111; = p.S7974* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/305 reads (6%) | called by muse, mutect2
- ZNF142 | c.4684G>A p.A1562T (on ENST00000411696 / NM_001379660.1; = p.A1362T on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- ZNF268 | c.2737A>G p.T913A | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF497 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 41/500 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ZNF823 | c.365G>C p.G122A (on ENST00000341191 / NM_001297610.2; = p.G78A on NM_017507.2) | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTA2 | c.316C>T p.L106= | Silent (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- CRB2 | c.654G>A p.T218= | Silent (SNP) | VAF 22/282 reads (8%) | catalogued as rs1222124015; called by muse, mutect2
- DCP1A | c.1527G>A p.Q509= | Silent (SNP) | VAF 44/430 reads (10%) | catalogued as COSV99588071; called by muse, mutect2, varscan2
- GABRG2 | c.171G>A p.L57= | Silent (SNP) | VAF 21/292 reads (7%) | called by muse, mutect2
- LILRB3 | c.537C>T p.A179= | Silent (SNP) | VAF 16/350 reads (5%) | catalogued as rs1392640297; called by muse, mutect2
- PIGM | c.840G>A p.L280= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- TP53TG5 | c.819G>C p.S273= | Silent (SNP) | VAF 34/453 reads (8%) | called by muse, mutect2
- TRAPPC13 | c.123C>T p.L41= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV51559851; called by muse, mutect2, varscan2
- UBR5 | c.5541T>C p.D1847= | Silent (SNP) | VAF 33/196 reads (17%) | called by muse, mutect2, varscan2
- XRN2 | c.405C>T p.V135= | Silent (SNP) | VAF 14/197 reads (7%) | called by muse, mutect2
- ZFR2 | c.162G>A p.P54= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs756593762, COSV53603470; called by muse, mutect2
- ZIM3 | c.300C>T p.L100= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs754470745, COSV54139668, COSV54139974; called by muse, mutect2
- IGFN1 | c.1242-3299G>T | Intron (SNP) | VAF 28/320 reads (9%) | called by muse, varscan2
- MST1L | n.367G>A | RNA (SNP) | VAF 37/461 reads (8%) | called by muse, mutect2, varscan2
- PITX1 | c.169+755C>G | Intron (SNP) | VAF 31/255 reads (12%) | called by muse, mutect2, varscan2
- SPATA9 | c.378+656C>G | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- TBC1D10A | c.-9G>A | 5'UTR (SNP) | VAF 20/196 reads (10%) | catalogued as rs1429113519; called by muse, mutect2, varscan2
- TERT | c.-45G>T | 5'UTR (SNP) | VAF 23/88 reads (26%) | catalogued as COSV57209080; called by muse, mutect2, varscan2
- WDR90 | c.*141T>A | 3'UTR (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2
